Somatic mutation profile of tumor specimen 0DFSSX from CCDI case PBBSMY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Meningioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,255 days).
Specimen 0DFSSX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9681f686-d529-44d5-8cb7-0318812e78b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFSS3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/931fe47d-7fb8-4083-ad12-d16a8dd525c0

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, Silent 2, Splice Region 1, RNA 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 264/383 reads (69%) | catalogued as rs121434259, CM930513, COSV58519659; ClinVar: pathogenic; called by muse, varscan2
- FN1 | c.566A>G p.H189R | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV60548349; called by muse, varscan2
- SPAG6 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 194/466 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs749967665, COSV57624170; called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 22/210 reads (10%) | called by muse, varscan2
- KIF7 | c.1424A>G p.Q475R | Missense Mutation (SNP) | VAF 227/574 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- MAP4K4 | c.857A>G p.H286R | Missense Mutation (SNP) | VAF 252/624 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs1167537044; called by muse, varscan2
- SKOR2 | c.45G>A p.A15= | Silent (SNP) | VAF 106/277 reads (38%) | catalogued as rs910714252; called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 20/198 reads (10%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 20/196 reads (10%) | called by muse, varscan2
- PCID2 | c.37-96G>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55814251; called by muse, varscan2
- PRDM11 | chr11:45228231 T>A | 3'Flank (SNP) | VAF 8/68 reads (12%) | catalogued as rs924592266; called by muse, varscan2
- SSPOP | n.10505A>G | RNA (SNP) | VAF 66/182 reads (36%) | called by muse, varscan2
